Somatic mutation profile of tumor specimen TCGA-KL-8328-01A (aliquot TCGA-KL-8328-01A-11D-2310-10) from TCGA case TCGA-KL-8328, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 60.2 years (21,976 days).
Specimen TCGA-KL-8328-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ee63ce0-9afc-4f9b-bbe6-d5d250425715.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KL-8328-11A (Solid Tissue Normal), aliquot TCGA-KL-8328-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00c67a0d-7622-49f2-9f07-7f07a8c8f89f

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, Nonsense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PKD2 | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 103/218 reads (47%) | catalogued as rs121918040, CM961124, COSV52937522; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANP32A | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs1489954326, COSV51189324, COSV51189995; called by muse, mutect2, varscan2
- BCLAF1 | c.788A>T p.H263L | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs1157427814, COSV100786726; called by muse, mutect2, varscan2
- C10orf120 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | catalogued as COSV61492672; called by muse, varscan2
- CHD4 | c.2828G>T p.R943L (on ENST00000357008 / NM_001363606.2; = p.R956L on NM_001273.5) | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV58896255; called by muse, mutect2, varscan2
- CHPF2 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 35/90 reads (39%) | catalogued as rs749209205; called by muse, mutect2, varscan2
- FNDC1 | c.4457G>A p.R1486H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs547791202; called by muse, mutect2, varscan2
- LRRK1 | c.5555C>T p.A1852V | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52627390; called by muse, mutect2, varscan2
- LSM14A | c.1175A>G p.N392S | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70885156; called by muse, mutect2, varscan2
- NFIA | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV100783341; called by muse, mutect2
- TACC3 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as COSV100508894; called by muse, mutect2, varscan2
- C10orf120 | c.560A>C p.E187A | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- FAM185A | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- NPTX2 | c.709T>G p.Y237D | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ZNF354C | c.941C>A p.T314N | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CCDC66 | c.1683C>T p.D561= (on ENST00000394672 / NM_001353147.1; = p.D527= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 190/404 reads (47%) | called by muse, varscan2
- CLTRN | c.357T>C p.N119= | Silent (SNP) | VAF 134/138 reads (97%) | called by muse, mutect2, varscan2
- MLXIPL | c.750C>T p.S250= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs578022743; called by muse, mutect2, varscan2
- PROP1 | c.198G>A p.P66= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs769315766, COSV57644591; called by muse, mutect2, varscan2
- SMARCA2 | c.1314T>A p.I438= | Silent (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
